Somatic mutation profile of tumor specimen 0DOLV9 from CCDI case PBCCHX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.9 years (1,058 days).
Specimen 0DOLV9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 374b1cda-df14-4ce7-acea-7c323f5b0966.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOLUR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ce7d5fd-f776-40c6-864b-e09e4489f029

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DROSHA | c.3637C>T p.R1213C | Missense Mutation (SNP) | VAF 58/1402 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV60772166; called by muse, mutect2
- FTCD | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 194/607 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as rs368782658; called by muse, mutect2, varscan2
- LIME1 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 132/526 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs746290002; called by muse, mutect2, varscan2
- CEP43 | c.301-89T>C | Intron (SNP) | VAF 8/239 reads (3%) | called by muse, mutect2
- CEP43 | c.301-88G>A | Intron (SNP) | VAF 8/248 reads (3%) | called by muse, mutect2
